Somatic mutation profile of tumor specimen MBCProject_2346_T1_WES (aliquot MBCProject_2346_T1_WES_1) from CMI case MBCProject_2346, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 45.8 years (16,733 days).
Specimen MBCProject_2346_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e0ca3d4-c67d-4ce4-a511-a14b72be24f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2346_SALIVA (Saliva), aliquot MBCProject_2346_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/332122a3-03f4-4321-9ff6-aaeee253d5a3

The open-access MAF lists 59 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 10, Intron 3, Frame Shift Del 3, Splice Site 3, 3'UTR 2, Splice Region 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 41/154 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3145G>C p.G1049R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as rs121913277, CM126700, COSV55874453, COSV55878564, COSV55919873; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP18 | c.1045C>T p.L349= | Splice Region (SNP) | VAF 27/129 reads (21%) | catalogued as rs577421005; called by muse, mutect2, varscan2
- ASPSCR1 | c.614G>C p.G205A | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV100144733; called by muse, mutect2, varscan2
- DACT3 | c.1808T>A p.V603E | Missense Mutation (SNP) | VAF 62/386 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100340470; called by muse, mutect2, varscan2
- F13A1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs769424362; called by muse, mutect2, varscan2
- HDAC10 | c.128T>A p.L43Q | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53136182; called by muse, mutect2, varscan2
- HHAT | c.564C>G p.C188W | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54792950; called by muse, mutect2
- HSD17B3 | c.894C>A p.H298Q | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV64558508; called by muse, mutect2, varscan2
- LTBP2 | c.3792G>T p.E1264D | Missense Mutation (SNP) | VAF 73/255 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV100001348; called by muse, mutect2, varscan2
- MBD2 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); catalogued as rs1218048946; called by muse, varscan2
- MINPP1 | c.641T>C p.M214T | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs780770929; called by muse, mutect2, varscan2
- MPDZ | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV100063037; called by muse, mutect2, varscan2
- NCSTN | c.1658A>G p.H553R | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1292182709; called by muse, mutect2
- RPS6KA1 | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1397175255; called by muse, mutect2, varscan2
- SETD5 | c.4277G>A p.R1426Q | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.068); catalogued as rs757364157; called by muse, mutect2, varscan2
- TCF20 | c.5471C>T p.S1824L | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs372854309; called by muse, mutect2
- TSC2 | c.2749C>T p.R917W | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781587135, COSV54780192; ClinVar: likely benign; called by muse, mutect2
- WFDC3 | c.163A>C p.K55Q | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54784172; called by muse, mutect2, varscan2
- ASRGL1 | c.876G>C p.K292N | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ATAD3C | c.23T>G p.L8R | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATP11B | c.1767G>C p.E589D | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.009); called by muse, mutect2
- C1QL2 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- CHKB | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 76/188 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- CYP4B1 | c.419T>G p.L140R | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- DBF4 | c.1570_1576del p.H524Yfs*8 | Frame Shift Del (DEL) | VAF 29/111 reads (26%) | called by mutect2, pindel, varscan2
- DNAH2 | c.6550G>A p.D2184N | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EFR3A | c.221T>A p.V74D | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- EXOC6B | c.388A>C p.T130P | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FAM110B | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPRASP1 | c.590A>T p.K197I | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- H4C11 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); called by muse, varscan2
- HBM | c.298-2A>G p.X100_splice | Splice Site (SNP) | VAF 65/193 reads (34%) | called by muse, mutect2, varscan2
- HERC2 | c.12139G>A p.G4047R | Missense Mutation (SNP) | VAF 47/208 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- KDM6A | c.451_458del p.K151Sfs*7 | Frame Shift Del (DEL) | VAF 45/167 reads (27%) | called by mutect2, pindel, varscan2
- NCOA5 | c.218G>C p.R73T | Missense Mutation (SNP) | VAF 17/349 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- NF1 | c.674_680delinsT p.E225_Y227delinsV | In Frame Del (DEL) | VAF 46/132 reads (35%) | called by pindel, varscan2*
- PIWIL1 | c.2083A>T p.S695C | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PLEKHA1 | c.790_794del p.S264Nfs*7 | Frame Shift Del (DEL) | VAF 20/94 reads (21%) | called by pindel, varscan2
- RRP12 | c.3705_3708+11del p.X1235_splice | Splice Site (DEL) | VAF 11/114 reads (10%) | called by mutect2, pindel
- SAGE1 | c.2006-1G>T p.X669_splice | Splice Site (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- VSIG2 | c.529T>A p.Y177N | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF704 | c.1016C>T p.T339I | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CIRBP | c.309C>T p.F103= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs1396484444; called by muse, varscan2
- CPSF1 | c.2079C>T p.S693= | Silent (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
- EPX | c.1527C>T p.I509= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs139335955; called by muse, mutect2, varscan2
- FAM120A | c.2340C>G p.A780= | Silent (SNP) | VAF 15/224 reads (7%) | catalogued as COSV99464389; called by muse, mutect2
- MAGEA8 | c.186C>T p.P62= | Silent (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
- OR6C68 | c.801C>T p.N267= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as rs779621199; called by muse, mutect2, varscan2
- SACS | c.2880G>A p.L960= | Silent (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- SMAD9 | c.585C>T p.H195= | Silent (SNP) | VAF 34/245 reads (14%) | catalogued as rs549804192; called by muse, mutect2, varscan2
- TUBB2B | c.309G>A p.K103= | Silent (SNP) | VAF 22/225 reads (10%) | catalogued as rs1271743963; called by muse, mutect2, varscan2
- VWA2 | c.1479C>T p.S493= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs1161942468; called by muse, mutect2, varscan2
- ARHGEF3 | c.62+27756G>T | Intron (SNP) | VAF 55/154 reads (36%) | called by muse, mutect2, varscan2
- NPEPPS | c.980+27T>G | Intron (SNP) | VAF 26/92 reads (28%) | called by muse, mutect2, varscan2
- RAB39B | c.-43G>A | 5'UTR (SNP) | VAF 9/129 reads (7%) | called by muse, mutect2
- SLC25A29 | c.*34C>T | 3'UTR (SNP) | VAF 18/132 reads (14%) | called by muse, mutect2, varscan2
- VPS45 | c.1493+5257G>C | Intron (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- ZNF99 | c.*3217A>G | 3'UTR (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
